Somatic mutation profile of tumor specimen MP2PRT-PAPJNL-TMP1-A (aliquot MP2PRT-PAPJNL-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPJNL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,085 days).
Specimen MP2PRT-PAPJNL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb595eab-d91f-4a2a-a19e-4db095f34b4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJNL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJNL-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34da5164-ab58-450c-b584-dda4a64e38e4

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT4 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 381/920 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs752698481; called by muse, mutect2
- DLGAP1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 179/407 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs376528545, COSV100233641; called by muse, mutect2, varscan2
- NDUFAF5 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52521622; called by muse, mutect2
- UBE2D3 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57660862; called by muse, mutect2, varscan2
- ADCK1 | c.1213_1214insTCTTACGCCCG p.E405Vfs*32 | Frame Shift Ins (INS) | VAF 38/283 reads (13%) | called by mutect2, pindel, varscan2
- HIRA | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 146/385 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- LONP1 | c.1653_1654insT p.M552Yfs*3 | Frame Shift Ins (INS) | VAF 160/402 reads (40%) | called by mutect2, pindel*, varscan2
- PXDN | c.1525G>T p.G509C | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRGJP1 | chr7:38276300 TTGAACCAACCAGTGGTATCACACCGGTCTAAGCTTCTACAAAAATCTCAG>CCTGGCGGAGTTTAA | Missense Mutation (DEL) | VAF 15/34 reads (44%) | called by muse*, pindel
- ADPRHL1 | c.1236G>A p.R412= | Silent (SNP) | VAF 153/902 reads (17%) | called by muse, mutect2, varscan2
- CNP | c.174G>T p.L58= | Silent (SNP) | VAF 256/606 reads (42%) | called by muse, mutect2, varscan2
- EYA4 | c.1131G>A p.V377= (on ENST00000531901 / NM_001301013.1; = p.V371= on NM_004100.5) | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as COSV62051070; called by muse, mutect2, varscan2
